Surgical pathology report (de-identified scan), TCGA case TCGA-30-1892, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1892-01A (Primary Tumor).

[page 1 of 4]
Accession Number: [REDACTED] Report Status: Final

Type: Surgical Pathology

Pathology Report [REDACTED] OMENTUM BIOPSY

Accessioned On: [REDACTED]

DIAGNOSIS:

SPECIMEN LABELED "OMENTUM":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "OMENTUM" (#2):

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "IMPLANTS FROM MESENTERY OF TRANSVERSE COLON":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "SMALL BOWEL IMPLANT":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "APPENDIX":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA, invasive in appendix wall.

SPECIMEN LABELED "CUL DE SAC TUMOR":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "LEFT TUBE AND OVARY":

Ovary:

PAPILLARY SEROUS ADENOCARCINOMA of the ovary (3.8 cm), grade 3.

Fallopian tube:

Serous cysts.

SPECIMEN LABELED "RIGHT TUBE AND OVARY":

Ovary:

PAPILLARY SEROUS ADENOCARCINOMA, metastatic, on surface and focally invasive in cortex.

Fallopian tube:

PAPILLARY SEROUS ADENOCARCINOMA in tube lumen and as mass at fimbriated end (1.0 cm diameter).

SPECIMEN LABELED "UTERUS AND CERVIX":

Cervix:

No significant pathologic change.

Endometrium:

Inactive.

Myometrium:

No significant pathologic change.

Serosa:

PAPILLARY SEROUS ADENOCARCINOMA, metastatic (0.4 cm), with extensive histiocytic reaction.

SPECIMEN LABELED "CUL DE SAC":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA with histiocytic reaction.

SPECIMEN LABELED "IMPLANT GREATER WALL CURVATURE OF STOMACH":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "DIAPHRAGMATIC IMPLANTS":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "SMALL BOWEL IMPLANT":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

SPECIMEN LABELED "MESENTERY":

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

TCGA-30-1892

[page 2 of 4]
CLINICAL DATA:

History: [REDACTED] with elevated CA125, ascites, abdominal carcinomatosis.

TISSUE SUBMITTED: 1. Omentum [REDACTED]
2. Omentum
3. Implants from mesentery of transverse colon
4. Small bowel implant
5. Appendix [REDACTED]
6. Cul de sac tumor
7. Left tube & ovary
8. Right tube & ovary
9. Uterus & cervix
10. Cul de sac
11. Implant greater wall curvature of stomach
12. Diaphragmatic implants
13. Small bowel implant
14. Mesentery

O.R. CONSULTATION:

SPECIMEN LABELED "#1 OMENTUM" (FSA):
Serous adenocarcinoma.

SPECIMEN LABELED "#5 APPENDIX" (GROSS ONLY):

Grossly consistent with metastasis to appendix.

GROSS DESCRIPTION:

The specimen is received fresh in fourteen parts, each labeled with the patient's name and unit number.

Part one, "omentum", consists of a 28.0 x 14.7 x 13.5 cm tan/white to yellow endurated focally hemorrhagic omental cake, with grossly evident tumor invasion. Gross photographs are taken. Representative sections of tumor and normal are submitted to tumor bank into [REDACTED] lab for special studies. Representative sections are submitted.

Micro sections:

Micro 1: frozen section A remnant, 2 frags, [REDACTED]

Micro 2: additional omentum, 2 frags, [REDACTED]

Part two, "omentum", consists of a 5.2 x 3.0 x 0.9 cm piece of omentum revealing 2.5 x 1.5 x 0.9 cm grossly apparent white nodule. Representative sections are submitted.

Micro 3: omentum, 1 frag, [REDACTED]

Part three, "implants from mesentery of transverse colon", consists of five yellow to white focally firm fragments of soft tissue measuring in aggregate of 3.5 x 2.5 x 0.5 cm. Representative sections are submitted.

Micro 4: implants from mesentery of transverse colon, 5 frags [REDACTED]

Part four, "small bowel implant", consists of multiple white/tan fragments of firm soft tissue measuring in aggregate 0.8 x 1.5 x 0.2 cm, the largest measuring 1.5 x 0.5 x 0.2 cm. The specimen is entirely submitted.

Micro 5: 6 frags, [REDACTED]

Part five, "appendix", consists of a 5.5 cm long by 0.6 cm in diameter appendix with a tan/yellow firm mass (5 x 4 x 2.2 cm) attached to serosa. A representative section is submitted to tissue bank. Representative sections are submitted.

Micro 6: external mass invading through serosa, 2 frags, [REDACTED]

Micro 7: mass in lumen, 1 frag, [REDACTED]

[page 3 of 4]
Part six, "cul de sac tumor", consists of one piece of white/tan soft tissue measuring 3.1 x 1.3 x 0.6 cm, and one piece of dark brown tissue measuring 1.5 x 0.8 x 0.2 cm grossly consistent with clot. The larger fragment has a brown to white cut surface. Representative sections are submitted.

Micro 8: cul de sac tumor, 4 frags, [REDACTED]

TCGA-30-1892

Part seven, "left tube & ovary", consists of a 3.8 x 3.2 x 2.5 cm lobulated white to tan mass attached to a fallopian tube measuring 4.5 cm in length by 0.4 cm in diameter. The mass has one cyst filled with clear serous fluid approximately 1 cm in diameter. The remaining portion of the mass is firm and solid with a mottled appearance ranging from white to brown. The outer surface has a greater than 10 papillary excrescences measuring approximately 0.1 to 0.2 cm in diameter each. Residual ovary is not identified. The mass has not grossly involved fallopian tube which has a patent lumen and a fimbriated end. The outer surface is inked black. Representative sections are submitted.

Micro 9-11: ovarian mass, 3 frags, [REDACTED]

Micro 12: fallopian tube, 4 frags, [REDACTED]

Part eight, "right tube & ovary", consists of a 3.2 x 1.7 x 0.7 cm ovary attached to a 4.5 cm in length by 0.4 cm in diameter tube. The ovary has a white bosselated surface, with approximately 20 pink papillary excrescences, the greatest of which is 0.3 cm in diameter. The ovary has a tan/pink cortex. The ovarian tube appears patent, although the fimbriated end has a firm, white mass measuring 1.0 x 0.7 x 0.3 cm attached to it. The outer surface is inked black. Representative sections are submitted.

Micro 13-14: ovary, 3 frags, [REDACTED]

Micro 15: fallopian tube, 4 frags, [REDACTED]

Micro 16: mass with fimbriated end, 2 frags, [REDACTED]

Part nine, "uterus & cervix", consists of a 51 gm specimen including an unopened uterus (6.5 x 4.5 x 2.5 cm). The exocervix (3.5 x 3 cm) is covered by smooth white glistening mucosa, with a brown stripe, 3 cm long by 0.3 cm wide likely procedure related. The external os is circular and measures 0.3 cm in diameter. The endocervical canal (1.8 cm in length) has a tan herringbone mucosa and multiple submucous cysts (approximately 5) measuring 0.1 cm in diameter. The endometrial cavity (2.2 cm cornu to cornu, 2.8 cm in length) has a tan velvety mucosa. The endometrium is on average 0.1 cm thick and the myometrium measures 1.5 cm in maximal thickness. The serosa is smooth and red/tan with a small white patch measuring approximately 0.4 cm in diameter on the posterior surface. The serosa and cut surfaces are inked black. Representative sections are submitted.

Micro 17: anterior cervix, 1 frag, [REDACTED]

Micro 18: posterior cervix, 1 frag, [REDACTED]

Micro 19: anterior LUS, 1 frag, [REDACTED]

Micro 20: posterior LUS, 1 frag, [REDACTED]

Micro 21: anterior endometrium, 2 frags, [REDACTED]

Micro 22: posterior endometrium including serosal patch, 2 frags, [REDACTED]

Part ten, "cul de sac", consists of multiple fragments of white nodular to brown soft tissue measuring in aggregate 2.8 x 2.8 x 0.7 cm. The specimen is entirely submitted.

Micro 23: 2 larger fragments, 4 frags, [REDACTED]

Micro 24: remaining frags, multiple frags, [REDACTED]

Part eleven, "implant greater wall curvature of stomach", consists of one white to brown firm nodule measuring 2.2 x 0.6 x 0.6 cm. The specimen is trisected and entirely submitted.

Micro 25: implant greater wall curvature of stomach, 3 frags, [REDACTED]

Part twelve, "diaphragmatic implants", consists of multiple fragments of tan/white soft tissue measuring 2 x 1.7 x 0.2 cm. The entire specimen is [REDACTED]

[page 4 of 4]
submitted.

Micro 26: diaphragmatic implants, multiple frags, [REDACTED]

Part thirteen, "small bowel implant", consists of two white/tan nodules, measuring 0.2 cm in diameter and 0.1 cm in diameter. The entire specimen is submitted.

Micro 27: small bowel implant, 2 frags, [REDACTED]

TCGA-30-1892

Part fourteen, "mesentary", consists of three white to brown nodules measuring 0.2 cm in diameter each. The entire specimen is submitted.

Micro 28: mesentary, 3 frags, [REDACTED]

Reports to: [REDACTED]

SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: APPENDIX, OTHER THAN INCIDENTAL

ADDITIONAL SPECIMEN TYPE: PERITONEUM BIOPSY

ADDITIONAL SPECIMEN TYPE: UTERUS W/ OR W/O ADNEXA- OTH THAN NEPLAST OR PROL

ADDITIONAL SPECIMEN TYPE: PERITONEUM BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

Source: NCI Genomic Data Commons file a430855d-a5b1-4e74-a06d-ae938563de33 (TCGA-30-1892.FB7C966C-9B16-4781-9C01-2DB480C88D63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).